Somatic mutation profile of tumor specimen MP2PRT-PAVJMZ-TMP1-A (aliquot MP2PRT-PAVJMZ-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVJMZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.4 years (525 days).
Specimen MP2PRT-PAVJMZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 945d4c51-a321-49b9-a5db-47183516b30e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVJMZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVJMZ-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/968282f1-4fef-4bfa-85ad-7b3fa9341dbd

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GOLGB1 | c.1750A>G p.R584G | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.053); catalogued as rs1218377282, COSV61468499; called by muse, mutect2
- PBX1 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- POFUT2 | c.753C>T p.D251= | Silent (SNP) | VAF 82/258 reads (32%) | catalogued as rs201577734; called by muse, mutect2, varscan2
